Somatic mutation profile of tumor specimen TCGA-TP-A8TT-01A (aliquot TCGA-TP-A8TT-01A-12D-A41K-08) from TCGA case TCGA-TP-A8TT, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 64.3 years (23,476 days).
Specimen TCGA-TP-A8TT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0070382a-6559-4068-81f4-5bd07297f6c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TP-A8TT-10A (Blood Derived Normal), aliquot TCGA-TP-A8TT-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5567956e-ea1e-4500-8408-27a73a86bd53

The open-access MAF lists 26 somatic variants for this specimen: 22 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 18, Silent 4, Nonsense Mutation 1, Splice Site 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APH1B | c.94A>T p.I32F | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); catalogued as COSV99971590; called by muse, mutect2, varscan2
- CHM | c.758G>T p.R253L | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100753511; called by muse, mutect2, varscan2
- DNAH9 | c.11834C>T p.A3945V | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.258); catalogued as rs376820901; called by muse, mutect2, varscan2
- GAS2L2 | c.2287C>T p.R763W | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs781885696; called by muse, mutect2, varscan2
- GLIPR1 | c.184C>G p.P62A | Missense Mutation (SNP) | VAF 32/177 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV99875788; called by muse, mutect2, varscan2
- MRGPRX4 | c.746T>C p.L249S | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as COSV100049772; called by muse, mutect2, varscan2
- OXA1L | c.159A>T p.K53N | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as COSV99591231; called by muse, mutect2, varscan2
- PCDH10 | c.3102G>T p.L1034F | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV99994105; called by muse, mutect2, varscan2
- PHYH | c.414+1G>A p.X138_splice | Splice Site (SNP) | VAF 10/41 reads (24%) | catalogued as COSV99538269; called by muse, mutect2, varscan2
- RGL3 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs779419722, COSV66506061; called by muse, mutect2, varscan2
- SIN3B | c.1150G>A p.G384R | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); catalogued as rs752227470, COSV56134324; called by muse, mutect2, varscan2
- SLC16A2 | c.1033T>C p.Y345H | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV99330882; called by muse, mutect2, varscan2
- SLC43A2 | c.1339C>G p.L447V | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100025128; called by muse, varscan2
- SYT11 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs528248189, COSV64174683, COSV64175384; called by muse, mutect2, varscan2
- TCF20 | c.5380G>A p.D1794N | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs945371130, COSV100166793; called by muse, mutect2, varscan2
- TMEM106B | c.608T>C p.I203T | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as COSV101188850; called by muse, mutect2, varscan2
- TNS4 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs200910076, COSV99563994; called by muse, mutect2, varscan2
- VRTN | c.1792G>T p.D598Y | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.063); catalogued as COSV56440139, COSV99832352; called by muse, mutect2, varscan2
- ZCCHC7 | c.778C>T p.R260* | Nonsense Mutation (SNP) | VAF 20/100 reads (20%) | catalogued as rs377509996; called by muse, mutect2, varscan2
- ZNF398 | c.691T>C p.S231P (on ENST00000475153 / NM_170686.3; = p.S60P on NM_020781.4) | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.806); catalogued as COSV100246981; called by muse, mutect2
- CARHSP1 | c.296_299del p.Y99Sfs*127 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | called by mutect2, pindel
- TRDV1 | c.166dup p.W56Lfs*19 | Frame Shift Ins (INS) | VAF 20/91 reads (22%) | called by mutect2, pindel, varscan2
- DSG3 | c.1611C>T p.A537= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as rs375966622; called by muse, mutect2, varscan2
- SLC39A10 | c.1977C>T p.S659= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as rs570834233, COSV62769241; called by muse, mutect2, varscan2
- SOAT2 | c.813C>T p.Y271= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as COSV100037556; called by muse, mutect2, varscan2
- ZNF804A | c.3495T>G p.A1165= | Silent (SNP) | VAF 36/125 reads (29%) | catalogued as COSV100169111; called by muse, mutect2, varscan2
